Somatic mutation profile of tumor specimen TCGA-EE-A2GS-06A (aliquot TCGA-EE-A2GS-06A-12D-A197-08) from TCGA case TCGA-EE-A2GS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 32.1 years (11,716 days).
Specimen TCGA-EE-A2GS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d01610c8-3a6f-4aaa-a999-f92df4d4c994.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GS-10A (Blood Derived Normal), aliquot TCGA-EE-A2GS-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f37c94f7-c954-44ae-9fa4-708e5308b480

The open-access MAF lists 404 somatic variants for this specimen: 275 protein-altering or splice-affecting, 120 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 252, Silent 120, Nonsense Mutation 11, Splice Region 7, Intron 4, Splice Site 4, 5'Flank 3, In Frame Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 118/253 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, varscan2
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 31/49 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52642291; called by muse, mutect2, varscan2
- ACOX2 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233895062, COSV57150112; called by muse, mutect2, varscan2
- ADAM32 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs748555532, COSV65952246; called by muse, varscan2
- ADGRV1 | c.5726C>T p.P1909L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.018); catalogued as COSV67991507; called by muse, mutect2, varscan2
- ADH4 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55501673; called by muse, mutect2, varscan2
- AGMAT | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65436108; called by muse, mutect2, varscan2
- AICDA | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as CM064966, COSV57565492; called by muse, mutect2, varscan2
- AKAP3 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs758083290, COSV57418998; called by muse, mutect2, varscan2
- ALB | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV55740630; called by muse, mutect2, varscan2
- AMER1 | c.2812G>A p.G938R | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV57656483; called by muse, mutect2, varscan2
- AMOT | c.2630C>T p.A877V (on ENST00000371959 / NM_001113490.1; = p.A468V on NM_133265.3) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV59066520; called by muse, mutect2, varscan2
- ANKFN1 | c.932T>C p.M311T | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1225710067, COSV59454665; called by muse, mutect2, varscan2
- APOB | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.16); catalogued as COSV51945398, COSV51958163; called by muse, mutect2, varscan2
- AQP1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 137/285 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as rs745651824, CD1213105, COSV61267649; called by muse, mutect2, varscan2
- AREG | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs765591544, COSV52644609; called by muse, mutect2, varscan2
- ARHGAP36 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52266328; called by muse, mutect2, varscan2
- ARNT | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV62231699; called by muse, mutect2, varscan2
- ASH1L | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV64211515; called by muse, mutect2, varscan2
- ASH1L | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV64211523; called by muse, mutect2, varscan2
- ATF2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV51372325; called by muse, mutect2, varscan2
- ATF6B | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 129/238 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64352364; called by muse, mutect2, varscan2
- ATF7IP2 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as rs1567184036, COSV61094656; called by muse, mutect2, varscan2
- ATG2A | c.2246G>A p.W749* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV65967960; called by muse, mutect2, varscan2
- ATXN7L2 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 252/564 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV60205552; called by muse, mutect2, varscan2
- AURKB | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs144169786, COSV60245008; called by muse, mutect2, varscan2
- B3GALT4 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 104/163 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65852016; called by muse, mutect2, varscan2
- BAHD1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1186022273, COSV69084369; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2, varscan2
- BMP7 | c.612G>A p.R204= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as rs142693632, COSV67781881; called by muse, mutect2, varscan2
- C4BPA | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65537105; called by muse, mutect2, varscan2
- C6 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs949631608, COSV54708939; called by muse, mutect2, varscan2
- C8orf34 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs774382540, COSV61389054; called by muse, mutect2, varscan2
- CALR3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as COSV54169592; called by muse, varscan2
- CARD10 | c.2059+1G>A p.X687_splice | Splice Site (SNP) | VAF 26/61 reads (43%) | catalogued as COSV52658982; called by muse, mutect2, varscan2
- CARD10 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52658994, COSV99324881; called by muse, mutect2, varscan2
- CATSPERB | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56431572, COSV99831781; called by muse, mutect2, varscan2
- CCNB2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55596350; called by muse, mutect2, varscan2
- CD163 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.889); catalogued as rs1162001846, COSV63135659; called by muse, mutect2, varscan2
- CD84 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 112/194 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV60869937; called by muse, mutect2, varscan2
- CDC42BPA | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1193882077, COSV62010729, COSV62016797; called by muse, mutect2, varscan2
- CDH19 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as COSV50968825; called by muse, mutect2, varscan2
- CEP164 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV54044345; called by muse, mutect2, varscan2
- CES2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV57697457; called by muse, mutect2, varscan2
- CFH | c.2494G>A p.G832R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411322; called by muse, mutect2, varscan2
- CHD6 | c.3541C>T p.P1181S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs532749294, COSV58560197; called by muse, mutect2, varscan2
- CHIA | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV58474881, COSV58477113; called by muse, mutect2, varscan2
- CHRDL1 | c.929G>A p.G310E (on ENST00000372045; = p.G316E on NM_145234.4) | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54327303; called by muse, mutect2, varscan2
- CHRNA1 | c.622G>A p.D208N (on ENST00000261007 / NM_001039523.3; = p.D183N on NM_000079.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as rs145421881, COSV53682848; called by muse, mutect2, varscan2
- CLEC14A | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV60563629; called by muse, mutect2, varscan2
- CLK2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 133/236 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs779399122, COSV62877876; called by muse, mutect2, varscan2
- CLOCK | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV59404011; called by muse, mutect2, varscan2
- CNGA2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV61704312; called by muse, mutect2, varscan2
- CNR2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65692744; called by muse, mutect2, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2, varscan2
- CNTNAP4 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV56673289, COSV56692997; called by muse, mutect2, varscan2
- COG7 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.17); catalogued as COSV56150361; called by muse, mutect2
- COL1A2 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51958870; called by muse, mutect2, varscan2
- COL6A6 | c.4897G>A p.G1633R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62032413; called by muse, mutect2, varscan2
- COL9A2 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65623134; called by muse, mutect2, varscan2
- CSF2RB | c.455G>A p.W152* | Nonsense Mutation (SNP) | VAF 52/107 reads (49%) | catalogued as COSV53259729; called by muse, varscan2
- CSNK1A1L | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as rs1317209838, COSV65789807; called by muse, mutect2
- CSNK1G1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV57307102, COSV57312016; called by muse, mutect2, varscan2
- CSPP1 | c.2053C>T p.P685S (on ENST00000676605; = p.P644S on NM_024790.6) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749876803, COSV51589471; called by muse, mutect2, varscan2
- CTAGE1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV66944172; called by muse, mutect2, varscan2
- CTCFL | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452421283, COSV54772844; called by muse, mutect2, varscan2
- CYP4Z1 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61966067; called by muse, mutect2, varscan2
- DEDD | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV63502022, COSV63502906; called by muse, varscan2
- DEDD | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100919141, COSV63502842; called by muse, varscan2
- DENND3 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396902563, COSV52804872; called by muse, mutect2, varscan2
- DENND5A | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs993483496, COSV60236509; called by muse, mutect2, varscan2
- DHX38 | c.3280C>T p.R1094C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51698133, COSV99194567; called by muse, mutect2, varscan2
- DHX58 | c.716A>T p.Q239L | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52427342; called by muse, mutect2, varscan2
- DMD | c.4345-1G>A p.X1449_splice | Splice Site (SNP) | VAF 30/104 reads (29%) | catalogued as COSV100822897; called by muse, mutect2, varscan2
- DNAH10 | c.5846G>A p.R1949Q (on ENST00000409039; = p.R1888Q on NM_207437.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369904884; called by muse, mutect2, varscan2
- DNAH5 | c.12929G>A p.S4310N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as COSV54241753; called by muse, mutect2, varscan2
- DNAH8 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV59467992; called by muse, mutect2, varscan2
- DOCK8 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV66634264; called by muse, mutect2, varscan2
- EBF2 | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV68779456; called by muse, mutect2, varscan2
- EFNA4 | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV99665353; called by muse, mutect2, varscan2
- EPCAM | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs989321602, COSV55393443, COSV55394028; called by muse, mutect2, varscan2
- ERC2 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55646965; called by muse, mutect2, varscan2
- ERN2 | c.2245C>T p.H749Y | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55623549; called by muse, mutect2, varscan2
- EXPH5 | c.2428C>T p.L810F | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV56205917; called by muse, mutect2, varscan2
- F7 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as COSV60647253; called by muse, mutect2, varscan2
- F8 | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV64273474, COSV64276877; called by muse, mutect2, varscan2
- FAM135A | c.3726T>G p.D1242E (on ENST00000370479 / NM_001351599.1; = p.D1029E on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV52056306; called by muse, mutect2, varscan2
- FAM47C | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV63729036; called by muse, mutect2, varscan2
- FAM71F1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59374461; called by muse, mutect2, varscan2
- FAT2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55825826; called by muse, mutect2, varscan2
- FAT4 | c.11413C>T p.H3805Y | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.946); catalogued as rs755511559, COSV58682472; called by muse, mutect2, varscan2
- FBXO38 | c.752A>T p.Y251F | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV57030088; called by muse, mutect2, varscan2
- FBXW10 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.121); catalogued as COSV57320259; called by muse, mutect2, varscan2
- FCRL4 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs201701822, COSV54859781; called by muse, mutect2, varscan2
- FERMT1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54090904; called by muse, mutect2
- FGD5 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs376575642; called by muse, mutect2, varscan2
- FLNA | c.5696C>T p.S1899F (on ENST00000369850 / NM_001110556.2; = p.S1891F on NM_001456.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61048414; called by muse, mutect2, varscan2
- FOXG1 | c.805A>C p.T269P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57398454; called by muse, mutect2, varscan2
- FOXR2 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59257801; called by muse, mutect2, varscan2
- GABRE | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV64821189; called by muse, mutect2, varscan2
- GABRE | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.543); catalogued as rs1010287857, COSV100944327, COSV64821201; called by muse, mutect2, varscan2
- GAD1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs1348687911, COSV60153504; called by muse, mutect2, varscan2
- GDF5 | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV65502554; called by muse, mutect2, varscan2
- GON4L | c.5083C>T p.P1695S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55199533; called by muse, mutect2, varscan2
- GPR141 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57732262; called by muse, mutect2, varscan2
- GRIA3 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52073545; called by muse, mutect2, varscan2
- GRIN2A | c.3511C>T p.P1171S | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.081); catalogued as rs768174483, COSV58048483; called by muse, mutect2, varscan2
- GRIN2A | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58048501; called by muse, mutect2, varscan2
- GRM1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV51121413, COSV51322349; called by muse, mutect2, varscan2
- GRM1 | c.702G>A p.G234= | Splice Region (SNP) | VAF 43/62 reads (69%) | catalogued as rs1255461814, COSV99268235, COSV99269019; called by muse, mutect2, varscan2
- GRM8 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58851039; called by muse, mutect2, varscan2
- GRPR | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 167/271 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs1344834217, COSV66669987; called by muse, mutect2, varscan2
- HBB | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as rs33922842, CM880039, CM910204, CX085154, COSV58942837; called by muse, mutect2, varscan2
- HHIP | c.1548G>A p.G516= | Splice Region (SNP) | VAF 18/43 reads (42%) | catalogued as COSV56842410; called by muse, mutect2, varscan2
- HPD | c.6G>A p.T2= | Splice Region (SNP) | VAF 23/64 reads (36%) | catalogued as rs377475703, COSV56643213; called by muse, mutect2, varscan2
- HSD17B14 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 126/176 reads (72%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV54414590; called by muse, mutect2, varscan2
- HTR7 | c.540G>A p.R180= | Splice Region (SNP) | VAF 28/37 reads (76%) | catalogued as COSV53290764; called by muse, mutect2, varscan2
- HTT | c.6268C>G p.L2090V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.319); catalogued as COSV61866375; called by muse, mutect2, varscan2
- IGHV3-43 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs751115881; called by muse, mutect2, varscan2
- IL1RAPL2 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV61170519, COSV61171045; called by muse, mutect2, varscan2
- IL4R | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV50156678; called by muse, mutect2, varscan2
- INA | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63976349; called by muse, mutect2, varscan2
- IQCA1 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99610426; called by muse, mutect2, varscan2
- IQCA1 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as COSV54508513; called by muse, mutect2, varscan2
- ITGAM | c.2218G>A p.G740R (on ENST00000648685 / NM_001145808.2; = p.G739R on NM_000632.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV54940217; called by muse, mutect2, varscan2
- ITGB8 | c.617G>C p.R206T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV56011968, COSV99752091; called by muse, mutect2, varscan2
- JPH3 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV52471695; called by muse, mutect2, varscan2
- KCND2 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.037); catalogued as rs151258092, CM1413104; called by muse, mutect2, varscan2
- KCNH6 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs146389731, COSV59000718; called by muse, mutect2, varscan2
- KCNK9 | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.395); catalogued as COSV57281027, COSV57285923; called by muse, mutect2, varscan2
- KLRD1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs781608711, COSV60273338, COSV60274015; called by muse, mutect2, varscan2
- KRTAP9-4 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV61898458; called by muse, mutect2, varscan2
- L3MBTL4 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.109); catalogued as COSV53133461; called by muse, mutect2, varscan2
- LARP4 | c.1546-2A>G p.X516_splice | Splice Site (SNP) | VAF 20/25 reads (80%) | catalogued as COSV53325354; called by muse, varscan2
- LAT2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV51922129; called by muse, mutect2
- LCMT1 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs755695509, COSV66726365; called by muse, mutect2, varscan2
- LGALS9 | c.875G>A p.R292Q (on ENST00000395473 / NM_009587.3; = p.R260Q on NM_002308.4) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs1265977883, COSV56350231; called by muse, mutect2
- LILRB4 | c.1147G>A p.E383K (on ENST00000391733 / NM_001278428.3; = p.E382K on NM_001278426.3) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54404468; called by muse, varscan2
- LPA | c.4531C>T p.R1511* | Nonsense Mutation (SNP) | VAF 54/68 reads (79%) | catalogued as rs770568866, COSV60296889, COSV60306904; called by muse, mutect2, varscan2
- LRP1B | c.2043G>A p.M681I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67253670; called by muse, mutect2, varscan2
- LRPPRC | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 139/359 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs546209070, COSV53235396, COSV53241262; called by muse, mutect2, varscan2
- LRRC32 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV52634544; called by muse, mutect2, varscan2
- LRRIQ4 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.16); PolyPhen benign (0.341); catalogued as rs771389654, COSV61619847; called by muse, varscan2
- LRRIQ4 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV61618877; called by muse, varscan2
- LRRTM2 | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 173/419 reads (41%) | catalogued as COSV51223776; called by muse, mutect2, varscan2
- LY6G6C | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 165/558 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs750441212, COSV65404931; called by muse, mutect2, varscan2
- MAGEC2 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV55997711, COSV55998813; called by muse, mutect2, varscan2
- MET | c.4096C>T p.P1366S | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59265823; called by muse, mutect2, varscan2
- MFSD4A | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 83/140 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.163); catalogued as COSV65656847; called by muse, mutect2
- MLX | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs143736694, COSV53818067; called by muse, mutect2, varscan2
- MRGPRX3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs143238196; called by muse, mutect2, varscan2
- MRGPRX3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV101283583; called by muse, mutect2, varscan2
- MUC16 | c.24302C>T p.S8101L | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as COSV67478602, COSV67481330; called by muse, mutect2, varscan2
- MUC3A | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0); catalogued as rs1176036035, COSV100115403; called by muse, mutect2, varscan2
- MUC5B | c.3136G>A p.G1046R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs757139899, COSV71594332; called by muse, mutect2, varscan2
- MYH11 | c.212T>A p.V71D | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55563298; called by muse, mutect2, varscan2
- MYO5B | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1446821416, COSV53226042; called by muse, mutect2, varscan2
- MYOCD | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58508465; called by muse, mutect2, varscan2
- NEUROD4 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54472942, COSV99670241; called by muse, mutect2, varscan2
- NOL4 | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV52355333; called by muse, mutect2, varscan2
- NPHS1 | c.2335G>A p.G779R | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62288768, COSV62290009; called by muse, mutect2, varscan2
- NUTM2G | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63617637; called by muse, mutect2, varscan2
- OR10T2 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV57782562; called by muse, mutect2, varscan2
- OR11H12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1370242111, COSV73569293; called by muse, mutect2, varscan2
- OR11L1 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV63315176; called by muse, mutect2, varscan2
- OR2B2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV57580403; called by muse, mutect2, varscan2
- OR2F2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 85/97 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs755644378, COSV101283840, COSV68833146; called by muse, mutect2
- OR51F2 | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.365); catalogued as COSV59065542; called by muse, mutect2, varscan2
- OR52L1 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100176347, COSV59988335; called by muse, mutect2, varscan2
- OR8D2 | c.197T>C p.L66S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62488807; called by muse, mutect2, varscan2
- OTUD6A | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.229); catalogued as COSV57974059; called by muse, mutect2, varscan2
- PAPPA2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 112/178 reads (63%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs866461390, COSV62773209, COSV62780685; called by muse, mutect2, varscan2
- PASD1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV64854385; called by muse, mutect2, varscan2
- PCDH18 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1236845539, CM160777, COSV61270688; called by muse, mutect2, varscan2
- PCDHA12 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV56530538; called by muse, mutect2, varscan2
- PCDHA5 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV65353977; called by muse, mutect2, varscan2
- PCDHB1 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60631200; called by muse, mutect2, varscan2
- PCDHB3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV50603654; called by muse, mutect2, varscan2
- PCDHGA12 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.003); catalogued as COSV52760896; called by muse, mutect2, varscan2
- PCDHGB3 | c.1507T>G p.S503A | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53998056; called by muse, mutect2, varscan2
- PCDHGB3 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53998075; called by muse, mutect2, varscan2
- PCLO | c.12397C>T p.R4133C | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372497499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCLO | c.8156G>A p.G2719E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs773627604, COSV61632500; called by muse, mutect2, varscan2
- PDE1A | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59530684; called by muse, mutect2, varscan2
- PDE9A | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52329579; called by muse, mutect2, varscan2
- PHACTR1 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 172/499 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV60666707; called by muse, mutect2, varscan2
- PHF3 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV50330009; called by muse, mutect2, varscan2
- PHKA2 | c.3610G>A p.A1204T | Missense Mutation (SNP) | VAF 167/283 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748453047, COSV101177084, COSV66053923; called by muse, mutect2, varscan2
- PIK3R5 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.598); catalogued as COSV52656814; called by muse, mutect2, varscan2
- PLCXD2 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV67338930; called by muse, mutect2, varscan2
- PLK2 | c.1813T>G p.W605G | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57109070; called by muse, mutect2, varscan2
- POU6F2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs368375577; called by muse, mutect2, varscan2
- PRAMEF4 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 148/350 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.941); catalogued as COSV52438635; called by muse, mutect2, varscan2
- PRDM1 | c.666A>T p.T222= | Splice Region (SNP) | VAF 81/212 reads (38%) | catalogued as COSV64846226; called by muse, mutect2, varscan2
- PRDM2 | c.1211A>C p.N404T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV52451976; called by muse, mutect2
- PRDM2 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781629418, COSV52451998; called by muse, mutect2
- PROC | c.908T>G p.L303R | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52166312; called by muse, mutect2, varscan2
- PSMD3 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as rs766083657, COSV52858989; called by muse, mutect2, varscan2
- PTH | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV56378753; called by muse, mutect2, varscan2
- PTPRT | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779663880, COSV61962183; called by muse, mutect2, varscan2
- QRICH1 | c.1662T>A p.C554* | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | catalogued as COSV62616842; called by muse, mutect2, varscan2
- RASD2 | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV53352007, COSV53353192; called by muse, mutect2, varscan2
- RASEF | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64588061; called by muse, mutect2, varscan2
- RASL11A | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV54080940; called by muse, mutect2, varscan2
- RERE | c.4471C>T p.R1491C | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61947021; called by muse, mutect2, varscan2
- RETREG2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV56088423; called by muse, mutect2, varscan2
- RFX6 | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs766770911, COSV60587555; called by muse, mutect2, varscan2
- RNF112 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.953); catalogued as rs369472711, COSV71327049; called by muse, varscan2
- ROBO4 | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV60626486; called by muse, mutect2, varscan2
- SASS6 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1448610619, COSV54926548; called by muse, mutect2, varscan2
- SEC14L4 | c.772-1G>A p.X258_splice | Splice Site (SNP) | VAF 27/69 reads (39%) | catalogued as COSV55400792; called by muse, mutect2, varscan2
- SEMG1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99725109, COSV99725592; called by muse, mutect2, varscan2
- SENP3 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53437020; called by muse, mutect2, varscan2
- SEPTIN6 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59716085; called by muse, mutect2, varscan2
- SF3A2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as COSV55554175, COSV55554901; called by muse, mutect2, varscan2
- SFMBT2 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 39/50 reads (78%) | catalogued as COSV62813949; called by muse, mutect2, varscan2
- SHKBP1 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs1399840003, COSV52542071; called by muse, mutect2, varscan2
- SLC16A14 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV54618964; called by muse, mutect2, varscan2
- SLC22A10 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV60422832; called by muse, mutect2, varscan2
- SLC25A52 | c.494C>T p.T165I (on ENST00000672005; = p.T155I on NM_001034172.4) | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.443); catalogued as COSV52503554; called by muse, mutect2, varscan2
- SLC4A10 | c.2671G>A p.E891K (on ENST00000446997 / NM_001354461.2; = p.E861K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55791437; called by muse, mutect2, varscan2
- SLC9A4 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54831814; called by muse, mutect2, varscan2
- SLC9C1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59889056, COSV59891027; called by muse, mutect2, varscan2
- SMARCA5 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV51646229; called by muse, mutect2
- SMCHD1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55264253; called by muse, mutect2, varscan2
- SMG1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV67173754; called by muse, mutect2, varscan2
- SNX13 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as rs746342625, COSV68063783; called by muse, mutect2, varscan2
- SOHLH2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.028); catalogued as rs12873478; called by muse, mutect2, varscan2
- SOX4 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55193610, COSV99782243; called by muse, mutect2, varscan2
- SPANXN2 | c.134A>T p.K45I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV100979776, COSV65128974; called by muse, varscan2
- SPHKAP | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as rs868542240, COSV60869806, COSV60876282; called by muse, mutect2, varscan2
- SPINT1 | c.1117A>T p.T373S (on ENST00000344051 / NM_181642.3; = p.T357S on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100689233; called by muse, mutect2, varscan2
- SPINT1 | c.1118C>T p.T373M (on ENST00000344051 / NM_181642.3; = p.T357M on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs199960318, COSV100689236; called by muse, mutect2, varscan2
- STAB1 | c.3368G>A p.G1123E | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as COSV58740725; called by muse, mutect2, varscan2
- SYTL4 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52169987; called by muse, mutect2, varscan2
- TAL1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV53747948; called by muse, mutect2, varscan2
- TAS2R38 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV71885813; called by muse, mutect2, varscan2
- TBCE | c.1088G>A p.G363D (on ENST00000366601; = p.G426D on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64006928, COSV64007417; called by muse, mutect2, varscan2
- TBCEL | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs769967053, COSV52458798; called by muse, mutect2, varscan2
- TEK | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754385594, COSV66231266; called by muse, mutect2, varscan2
- TIE1 | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65249673; called by muse, mutect2, varscan2
- TMEM108 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs79118437, COSV58878167; called by muse, mutect2, varscan2
- TNRC6B | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753937261, COSV57303133; called by muse, mutect2, varscan2
- TNXB | c.516T>G p.D172E | Missense Mutation (SNP) | VAF 235/428 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV64484902; called by muse, mutect2, varscan2
- TRPC4 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV59000571; called by muse, mutect2, varscan2
- TRPC5 | c.1607A>G p.N536S | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53298486; called by muse, mutect2, varscan2
- TTLL10 | c.1401+7C>T | Splice Region (SNP) | VAF 14/38 reads (37%) | catalogued as COSV101016931; called by muse, varscan2
- TTN | c.72362C>T p.T24121I (on ENST00000591111; = p.T16697I on NM_003319.4) | Missense Mutation (SNP) | VAF 49/95 reads (52%) | PolyPhen benign (0.242); catalogued as COSV60226479; called by muse, mutect2, varscan2
- TTN | c.53624T>A p.I17875N (on ENST00000591111; = p.I10451N on NM_003319.4) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | PolyPhen probably damaging (0.974); catalogued as COSV60226524; called by muse, mutect2, varscan2
- TUT4 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs928171035, COSV57117677; called by muse, mutect2, varscan2
- TXLNB | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs199860574, COSV64445018, COSV64446028; called by muse, mutect2, varscan2
- UBE3B | c.525G>A p.W175* | Nonsense Mutation (SNP) | VAF 97/237 reads (41%) | catalogued as COSV55096308; called by muse, mutect2, varscan2
- VANGL2 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63605076; called by muse, mutect2, varscan2
- VPS13D | c.6698C>T p.S2233F | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182329899, COSV50662274; called by muse, mutect2, varscan2
- VWA5A | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1011399433, COSV64413838; called by muse, mutect2, varscan2
- VWC2L | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs370205207; called by muse, mutect2, varscan2
- WARS1 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV59926735; called by muse, mutect2, varscan2
- WNT5B | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV60198627; called by muse, mutect2, varscan2
- ZBED2 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV51919972; called by muse, mutect2, varscan2
- ZBTB11 | c.1616T>C p.V539A | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as COSV57246247; called by muse, mutect2, varscan2
- ZC3H3 | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52792879; called by muse, mutect2
- ZC3H4 | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.306); catalogued as COSV53415465; called by muse, mutect2, varscan2
- ZFHX3 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1275046971, COSV51727735; called by muse, mutect2, varscan2
- ZFHX4 | c.5611G>A p.E1871K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV50643817; called by muse, mutect2, varscan2
- ZFYVE26 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs752300050, COSV61328449, COSV61333019; called by muse, mutect2, varscan2
- ZNF385D | c.503T>G p.V168G | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV55763227, COSV55767362; called by muse, mutect2, varscan2
- ZNF480 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867577390, COSV57997389; called by muse, mutect2, varscan2
- ZNF676 | c.1124G>A p.G375E (on ENST00000650058; = p.G343E on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101236211, COSV68094205, COSV68095102; called by muse, mutect2, varscan2
- ZNF780A | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV61816091; called by muse, mutect2, varscan2
- ZNF831 | c.5015G>A p.R1672Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777114010, COSV64041485; called by muse, mutect2, varscan2
- GAS2L2 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TRAV19 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TYR | c.287_295del p.M96_F98del | In Frame Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- ABCC8 | c.708C>T p.F236= | Silent (SNP) | VAF 259/594 reads (44%) | catalogued as COSV56848572; called by muse, mutect2, varscan2
- ACTRT3 | c.342C>T p.N114= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV57754929; called by muse, mutect2, varscan2
- ADAMTS10 | c.1869G>A p.G623= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1173983145, COSV54357339; called by muse, mutect2, varscan2
- ADAMTS2 | c.3216G>A p.R1072= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs1233299160, COSV52385454; called by muse, mutect2, varscan2
- ADAP2 | c.448C>T p.L150= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV58296755; called by muse, mutect2, varscan2
- ADGRF4 | c.1110C>T p.I370= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as COSV51955395; called by muse, mutect2, varscan2
- AP1M1 | c.390C>T p.I130= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV52227997; called by muse, mutect2, varscan2
- ARHGAP39 | c.2190C>T p.P730= | Silent (SNP) | VAF 45/84 reads (54%) | catalogued as rs1320280171, COSV52774175; called by muse, mutect2, varscan2
- ATP11C | c.1908C>T p.F636= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs747770080, COSV59559953; called by muse, mutect2, varscan2
- BARX2 | c.405G>A p.R135= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1340068174, COSV55651693; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4260C>T p.F1420= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as rs535585040, COSV63244701; called by muse, mutect2, varscan2
- BRDT | c.1779A>G p.E593= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV62866375; called by muse, mutect2, varscan2
- BSND | c.822G>A p.K274= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV64871008; called by muse, mutect2, varscan2
- BTNL8 | c.39G>A p.K13= | Silent (SNP) | VAF 118/273 reads (43%) | catalogued as rs1318058151, COSV51460335; called by muse, mutect2, varscan2
- CD101 | c.1683C>T p.S561= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV56719812; called by muse, mutect2, varscan2
- CD2 | c.822G>A p.Q274= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs745624462, COSV65644610; called by muse, mutect2, varscan2
- CFAP20DC | c.939C>T p.A313= (on ENST00000482387 / NM_001351530.2; = p.A188= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs1297484435, COSV55924689; called by muse, mutect2, varscan2
- CGNL1 | c.879C>T p.S293= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV55572341; called by muse, mutect2, varscan2
- CNTN4 | c.246G>A p.G82= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs751787735, COSV68562064, COSV68584303; called by muse, mutect2, varscan2
- CYP2C19 | c.1128C>T p.F376= | Silent (SNP) | VAF 32/46 reads (70%) | catalogued as rs267602637, COSV64907826; called by muse, mutect2, varscan2
- CYP2F1 | c.339C>T p.I113= | Silent (SNP) | VAF 125/169 reads (74%) | catalogued as rs568092421, COSV58527489; called by muse, mutect2, varscan2
- CYP4F3 | c.165G>A p.P55= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs150573744; called by muse, mutect2, varscan2
- DCHS1 | c.5893C>T p.L1965= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV55039959; called by muse, mutect2, varscan2
- DEDD | c.714C>G p.S238= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as COSV100919140; called by muse, varscan2
- DEFA6 | c.210C>T p.F70= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as rs1002623522, COSV52406190; called by muse, mutect2, varscan2
- DENND5A | c.501C>T p.P167= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs146129513; called by muse, mutect2, varscan2
- DNAH1 | c.10764C>T p.S3588= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs375328522; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH2 | c.2769C>T p.P923= | Silent (SNP) | VAF 87/220 reads (40%) | catalogued as COSV66723408; called by muse, mutect2, varscan2
- DNAH5 | c.9561C>T p.F3187= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs761332828, COSV54204193; called by muse, mutect2, varscan2
- DOCK2 | c.3057G>A p.T1019= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs150071550, COSV56943732; called by muse, mutect2, varscan2
- DPRX | c.417C>T p.V139= | Silent (SNP) | VAF 66/273 reads (24%) | catalogued as COSV64949860; called by muse, mutect2, varscan2
- DSCAM | c.4689C>T p.F1563= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs201376842, COSV68023011; called by muse, mutect2, varscan2
- EFNA4 | c.228C>T p.Y76= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV99665355; called by muse, mutect2, varscan2
- EP300 | c.3198C>T p.Y1066= | Silent (SNP) | VAF 93/219 reads (42%) | catalogued as COSV54340190; called by muse, mutect2, varscan2
- FAM163A | c.282C>T p.H94= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as COSV59204998; called by muse, mutect2, varscan2
- FAM170A | c.543C>T p.L181= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV58926400; called by muse, mutect2, varscan2
- GALNT16 | c.630G>A p.L210= | Silent (SNP) | VAF 77/173 reads (45%) | catalogued as COSV61887038; called by muse, mutect2, varscan2
- GEM | c.774G>A p.R258= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV52598262; called by muse, mutect2, varscan2
- GLIS1 | c.1522C>T p.L508= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV56553273; called by muse, mutect2, varscan2
- GRIN2A | c.4380C>T p.I1460= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs769629103, COSV58029601; called by muse, mutect2, varscan2
- HBG2 | c.264G>A p.Q88= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV57964190; called by muse, mutect2, varscan2
- IGHA1 | c.1005A>G p.K335= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- IQCA1 | c.1740G>A p.G580= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV54497132; called by muse, mutect2, varscan2
- ISL1 | c.777G>A p.G259= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV57933850; called by muse, mutect2, varscan2
- KCND2 | c.105G>A p.R35= | Silent (SNP) | VAF 89/253 reads (35%) | catalogued as rs776674171, COSV58573522, COSV58594633; called by muse, mutect2, varscan2
- KCNH8 | c.2589C>T p.T863= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV60471518; called by muse, mutect2, varscan2
- KCNJ9 | c.159G>A p.V53= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1265760135, COSV63632275; called by muse, mutect2, varscan2
- KHDC3L | c.549C>T p.L183= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV64863799; called by muse, mutect2
- LGALS9 | c.510C>T p.F170= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs1232611812, COSV56350218; called by muse, mutect2, varscan2
- LRFN1 | c.1395C>T p.S465= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs377518809; called by muse, mutect2
- LRP6 | c.2712C>T p.C904= | Silent (SNP) | VAF 193/526 reads (37%) | catalogued as rs1192616932, COSV53791462; called by muse, mutect2, varscan2
- LRRC14B | c.927G>A p.L309= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99361084; called by muse, mutect2
- LRRIQ1 | c.2904G>A p.L968= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs949936995, COSV67835534; called by muse, mutect2, varscan2
- M1AP | c.420C>T p.S140= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs1485240211, COSV51846999; called by muse, mutect2, varscan2
- MAGEC1 | c.3246G>A p.R1082= | Silent (SNP) | VAF 97/224 reads (43%) | catalogued as COSV53568794; called by muse, mutect2, varscan2
- MARCO | c.285C>T p.S95= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as COSV59056716; called by muse, mutect2, varscan2
- MCF2 | c.1266G>A p.R422= | Silent (SNP) | VAF 117/263 reads (44%) | catalogued as COSV58479752, COSV58491104; called by muse, mutect2, varscan2
- MGAM | c.5286G>A p.G1762= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs745786997, COSV72073721, COSV72075224; called by muse, mutect2, varscan2
- MOCS1 | c.147C>T p.F49= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV57937705, COSV57938821; called by muse, mutect2, varscan2
- MOV10L1 | c.1573C>T p.L525= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV53176315; called by muse, mutect2, varscan2
- MRO | c.42C>T p.S14= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99839552; called by muse, mutect2, varscan2
- MSRA | c.354C>T p.V118= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs561150329, COSV57805726; called by muse, mutect2, varscan2
- MXRA5 | c.4740A>G p.V1580= | Silent (SNP) | VAF 64/221 reads (29%) | catalogued as COSV54243878; called by muse, mutect2, varscan2
- MXRA8 | c.561G>A p.V187= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs781555385, COSV58511339; called by mutect2, varscan2
- MYH6 | c.5019C>T p.I1673= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs397516773, COSV62452995; ClinVar: likely benign; called by muse, mutect2, varscan2
- NKIRAS1 | c.72C>T p.L24= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV66248612; called by muse, mutect2, varscan2
- NOVA1 | c.567G>A p.K189= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV57483266; called by muse, mutect2, varscan2
- NPAP1 | c.2934G>A p.K978= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV61509593; called by muse, mutect2, varscan2
- NR3C1 | c.1462C>T p.L488= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV51545486; called by muse, mutect2, varscan2
- OBSCN | c.12084G>A p.Q4028= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs978197900, COSV52806084; called by muse, mutect2, varscan2
- OR11H12 | c.516G>A p.L172= | Silent (SNP) | VAF 48/268 reads (18%) | catalogued as COSV73569312; called by muse, varscan2
- OR14A16 | c.240C>T p.I80= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs200580825, COSV62926143; called by muse, mutect2, varscan2
- OR1E1 | c.426C>T p.L142= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs144699002; called by muse, mutect2, varscan2
- OR4C6 | c.924G>A p.G308= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1292041535, COSV58602981; called by muse, mutect2, varscan2
- OR5AK2 | c.909G>A p.V303= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV58805001; called by muse, mutect2, varscan2
- OR5D16 | c.849G>A p.V283= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as rs1434281368, COSV101004002, COSV65722367; called by muse, mutect2, varscan2
- OR6C74 | c.735C>T p.V245= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs776449609, COSV59606052; called by muse, mutect2, varscan2
- OR8B12 | c.183C>T p.F61= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs564116870, COSV60912352; called by muse, mutect2, varscan2
- OR8B8 | c.705C>T p.S235= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as rs1293445708, COSV60145293; called by muse, mutect2, varscan2
- PLG | c.1458G>A p.G486= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as rs141539231, COSV51984908; called by muse, mutect2, varscan2
- PLXNA3 | c.5364G>A p.V1788= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV63754998; called by muse, mutect2, varscan2
- PPFIA4 | c.1569A>T p.T523= (on ENST00000447715; = p.T498= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV55319204; called by muse, mutect2, varscan2
- PRLR | c.1644G>A p.K548= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV51498415; called by muse, mutect2, varscan2
- PRSS54 | c.1101G>A p.R367= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV54687023; called by muse, mutect2, varscan2
- PSTPIP2 | c.591C>T p.T197= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as rs750776412, COSV68958512; called by muse, mutect2, varscan2
- RIC1 | c.3666C>T p.S1222= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as COSV52613227; called by muse, mutect2, varscan2
- RPN2 | c.567T>G p.A189= | Silent (SNP) | VAF 71/145 reads (49%) | catalogued as COSV52907747; called by muse, mutect2, varscan2
- RYR2 | c.6720G>A p.L2240= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63702303; called by muse, mutect2, varscan2
- SAPCD2 | c.804C>T p.R268= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV68836751; called by muse, mutect2, varscan2
- SCAF4 | c.2256C>T p.S752= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV54590471; called by muse, mutect2, varscan2
- SCN11A | c.549C>T p.F183= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV56567084; called by muse, mutect2, varscan2
- SCN11A | c.105G>A p.K35= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as rs780129768, COSV56570695, COSV56579098; called by muse, mutect2, varscan2
- SCP2D1 | c.402C>T p.F134= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV53858220; called by muse, mutect2, varscan2
- SGO2 | c.2937C>T p.S979= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV63416637; called by muse, mutect2, varscan2
- SLC6A1 | c.525C>T p.S175= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55117489; called by muse, mutect2
- SMURF2 | c.1371C>T p.F457= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV52317979; called by muse, mutect2, varscan2
- SOGA1 | c.888C>T p.I296= | Silent (SNP) | VAF 53/134 reads (40%) | catalogued as rs1165614001, COSV52926330; called by muse, mutect2, varscan2
- SPTLC3 | c.966C>T p.I322= | Silent (SNP) | VAF 71/202 reads (35%) | catalogued as COSV65467276; called by muse, mutect2, varscan2
- SRRM2 | c.1452C>T p.S484= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV57078010; called by muse, mutect2, varscan2
- TBX18 | c.1380G>A p.V460= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV63737591; called by muse, mutect2, varscan2
- TECTA | c.3303C>T p.I1101= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs375594822; called by muse, mutect2, varscan2
- TENM1 | c.2832C>T p.F944= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV64438729; called by muse, mutect2, varscan2
- THSD7B | c.1518G>A p.G506= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV55649299; called by muse, mutect2
- TMCO3 | c.1102C>T p.L368= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV64807089; called by muse, mutect2, varscan2
- TRAJ39 | c.64C>T p.*22= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1348162547; called by muse, mutect2, varscan2
- TRAV21 | c.132C>T p.F44= | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- TRDV2 | c.120C>T p.L40= | Silent (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- TRPV6 | c.474G>A p.Q158= | Silent (SNP) | VAF 56/63 reads (89%) | catalogued as COSV63892881; called by muse, mutect2, varscan2
- TXN2 | c.492G>T p.L164= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV53398094; called by muse, mutect2, varscan2
- UAP1 | c.267C>T p.A89= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV54852586; called by muse, mutect2, varscan2
- UBXN10 | c.630G>A p.R210= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV66772458; called by muse, mutect2, varscan2
- VCPIP1 | c.1776C>T p.F592= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs762143236, COSV60049355; called by muse, mutect2, varscan2
- VSIG1 | c.1044G>A p.L348= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV54261180; called by muse, mutect2, varscan2
- WBP11 | c.1134C>T p.S378= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV53764056; called by muse, mutect2, varscan2
- WDR45B | c.462C>T p.S154= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV66408931; called by muse, mutect2, varscan2
- WHRN | c.1959C>T p.S653= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as rs376355638; called by muse, mutect2, varscan2
- ZNF28 | c.1176C>T p.F392= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as rs767026087, COSV60424211; called by muse, mutect2, varscan2
- ZNF536 | c.366C>T p.D122= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV62818972; called by muse, mutect2, varscan2
- ZNF676 | c.1653C>T p.I551= (on ENST00000650058; = p.I519= on NM_001001411.3) | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV68094200; called by muse, mutect2, varscan2
- ZW10 | c.2262C>T p.S754= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV52318461; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824454 G>A | 5'Flank (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208250 C>T | 5'Flank (SNP) | VAF 47/110 reads (43%) | catalogued as rs1350904859; called by muse, mutect2, varscan2
- CAPS2 | c.1670-2667C>T | Intron (SNP) | VAF 22/45 reads (49%) | catalogued as COSV60827558; called by muse, mutect2, varscan2
- LINC00173 | n.779C>T | RNA (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- MFRP | chr11:119343866 G>A | 5'Flank (SNP) | VAF 51/111 reads (46%) | catalogued as rs752690524, COSV64127934; called by muse, mutect2
- PHKB | c.2427+980C>T | Intron (SNP) | VAF 27/54 reads (50%) | catalogued as rs766475317, COSV100068546; called by muse, mutect2, varscan2
- TTN | c.10360+2330A>C | Intron (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100630479; called by muse, mutect2, varscan2
- UROC1 | c.903-537T>C | Intron (SNP) | VAF 31/86 reads (36%) | catalogued as rs867759189, COSV52036854; called by muse, mutect2, varscan2
- ZNF839 | c.-26G>A | 5'UTR (SNP) | VAF 13/26 reads (50%) | catalogued as COSV51758647; called by muse, mutect2, varscan2
